Surgical pathology report (de-identified scan), TCGA case TCGA-Z2-AA3S, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site IDI-IRCCS, specimen TCGA-Z2-AA3S-06A (Metastatic).

Histology number:

Sex: M

Age:

Lesion site: Right Axillary

Macroscopy:

Oval fragment of adipose tissue of 12x9.5x4.5 cm containing a partially necrotic whitish mass with a maximum diameter of 10 cm. Included representative sections

Microscopy:

Diagnosis:

Massive lymph node metastasis of melanoma. As diagnostic help, immunohistochemical staining for S100 has been performed.
BRAF (Real time PCR with test 4800 for mutation V600
Negative

Proposed by:

Biopsy by:

Division: Plastic surgery

Date of Biopsy:

Accepted:

Pathology Report Date:

Pathology Report:

ICD-O-3

Melanoma NOS 8720/3

Site: Lymph node, axilla C77.3

AS 1/17/14

Source: NCI Genomic Data Commons file 3f421024-cce4-4251-a36d-2b8d6b9523bf (TCGA-Z2-AA3S.48FB1191-7102-4E62-8A56-A3991807AB6D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).